Surgical pathology report (de-identified scan), TCGA case TCGA-MA-AA42, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-MA-AA42-01A (Primary Tumor).

[page 1 of 3]
Results SURGICAL PATHOLOGY

Entry Date _____

Component Results

Component

Surgical Pathology

(note)

Name

Date

Hospital Number

Location

ICC-0-3
Carcinoma, squamous cell NOS 8070/3
Site Cervix NOS C53.9
JW 4/11/14

SURGICAL PATHOLOGY

Accession #:

Collected:

Received:

ADDENDUM- IMMUNOHISTOCHEMISTRY

Results-Comments

EBV by in-situ hybridization is negative. HPV immunohistochemical stain is negative. The squamous cell carcinoma appears poorly differentiated, however, there are also features suggestive of a possible lymphoepithelial-like carcinoma, which is a subtype of squamous cell carcinoma with a better prognosis than the typical poorly differentiated squamous cell carcinoma.

Dr. _____ has reviewed this case and agrees.

End of Addendum Report or Additional Results

PATHOLOGIC DIAGNOSIS

CERVIX, BIOPSY:

- FRAGMENTS OF INVASIVE SQUAMOUS CELL CARCINOMA
- PENDING ADDITIONAL WORKUP (SEE COMMENT)

Comment

The biopsy is fragmented and the depth of invasion cannot be assessed. The tumor spans the entirety of tissue fragments with the largest fragment of tumor measuring 4.0 mm in greatest dimension.

Immunohistochemical stains show that the tumor cells are positive for CK 5/6, p63, and p16 and negative for CEA and S100. The morphologic and immunohistochemical features support the diagnosis is squamous cell carcinoma. The morphologic features, however, are unusual and further classification is pending additional workup. The final diagnosis will be reported in an addendum.

Dr. _____ was notified of the results on _____ at _____

Dr. _____ and Dr. _____ have reviewed this case and agree with the diagnosis of squamous cell carcinoma.

[page 2 of 3]
Pertinent Clinical Information

Pertinent History/Operative Findings: History of cervical cancer.

Specimen Material: Cervical biopsy.

Gross Description

The specimen is received in one part labeled with the patient's name and medical record number.

Received in formalin and labeled "CERVICAL BIOPSY" are multiple red-brown portions of clotted blood and soft tissue measuring 2.0 x 2.0 x 0.4 cm in aggregate. The specimen is submitted in toto in cassettes A1 and A2.

Pathologists' Assistant

Microscopic Description
Performed.

****Electronically Signed Out****

Staff Pathologist

Result History

SURGICAL PATHOLOGY (Order

on

Order Result History Report.

Lab Information

Resulting Lab

Order Information

Order Date

Order Time

Result Information

Result Date and Time

Status
Edited Result -
FINAL

Priority
Routine

Received Date/Time

Received Date

Received Time

Order Providers

Authorizing Provider

Encounter Provider

Encounter

[View Encounter](#)

Order

SURGICAL PATHOLOGY

Order

Administration Details

No Administrations
Recorded

Order Information

[page 3 of 3]
Order Date/Time

Release Date/Time
None

Start Date/Time

End Date/Time
None

Order Details

Frequency
None

Duration
None

Priority
Routine

Order Class
Normal

Quantity

Ordering Quantity
1

Transfer Service

Collection Information

Collection Date

Collection Time

Resulting Agency

Provider Information

Ordering User

Authorizing Provider

Attending Provider(s)

Order-Level Documents:

There are no order-level documents.

Encounter

[View Encounter](#)

Orders Needing Specimen Collection

**** None ****

Source: NCI Genomic Data Commons file f4a1aca4-15f8-4929-8e41-0dcfcc96e508 (TCGA-MA-AA42.62F4EBB5-6F2F-4D4C-817E-88EEF577BF1C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).